Somatic mutation profile of tumor specimen MMRF_2308_1_BM_CD138pos (aliquot MMRF_2308_1_BM_CD138pos_T1_KHS5U_L12850) from MMRF case MMRF_2308, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.6 years (27,255 days).
Specimen MMRF_2308_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f91706-f13f-4387-8378-46622128325e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2308_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2308_1_PB_CD3pos_C2_KHS5U_L12849; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33a96c5d-cb18-41c3-b6cf-54ab613fabd0

The open-access MAF lists 52 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 17, Silent 5, Intron 5, RNA 3, 5'UTR 1, Nonsense Mutation 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as rs373876511, COSV54359603, COSV99547505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, varscan2
- ARHGEF28 | c.3602C>T p.S1201F | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99708124; called by muse, mutect2, varscan2
- FANK1 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs778484321; called by muse, mutect2, varscan2
- IGLL5 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, mutect2, varscan2
- IGLV3-1 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs375057861; called by muse, varscan2
- IKBKB | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1217007648, COSV60595911, COSV60598768; called by muse, mutect2
- SCIN | c.1469C>T p.P490L (on ENST00000297029 / NM_001112706.3; = p.P243L on NM_033128.3) | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753723296; called by muse, mutect2, varscan2
- ZEB1 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775177081; called by muse, mutect2
- ADAMTS10 | c.2324C>A p.T775N | Missense Mutation (SNP) | VAF 102/197 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CYP4V2 | c.449T>C p.L150S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EHD2 | c.1606C>G p.R536G | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HMX3 | c.71C>G p.P24R | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIPA1 | c.424A>C p.K142Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.951); called by muse, mutect2
- SDK2 | c.1402T>C p.S468P | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SERPINE1 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- SLC17A5 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUFM | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UBR5 | c.6998G>A p.R2333Q | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CTNND2 | c.1656G>T p.L552= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV100475056; called by muse, mutect2, varscan2
- KCNJ6 | c.417C>T p.F139= | Silent (SNP) | VAF 23/223 reads (10%) | catalogued as COSV55712515; called by muse, mutect2
- LRRFIP2 | c.1134A>G p.K378= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs753902852; called by muse, mutect2, varscan2
- PLEKHA7 | c.3141C>T p.S1047= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- ZNF445 | c.1248C>T p.G416= | Silent (SNP) | VAF 17/296 reads (6%) | called by muse, mutect2
- ALG6 | c.*430C>T | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- C8orf74 | c.242-5866C>T | Intron (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- CDHR1 | c.*2524C>T | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- CLEC16A | c.*908C>G | 3'UTR (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- CRTC3 | c.352-3327C>T | Intron (SNP) | VAF 4/85 reads (5%) | called by muse, mutect2
- DUSP13 | c.*861C>T | 3'UTR (SNP) | VAF 8/88 reads (9%) | catalogued as rs748955537; called by muse, mutect2
- EN2 | c.*305A>C | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- EPC1 | chr10:32268578 A>G | 3'Flank (SNP) | VAF 53/132 reads (40%) | called by muse, mutect2, varscan2
- FAT3 | c.*2230T>A | 3'UTR (SNP) | VAF 64/110 reads (58%) | called by muse, mutect2, varscan2
- FLJ40288 | n.1345C>T | RNA (SNP) | VAF 51/95 reads (54%) | catalogued as rs374749324; called by muse, varscan2
- KIF3A | c.*2286G>T | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- LAMC2 | c.*1151T>A | 3'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- LINC02291 | n.615T>C | RNA (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- MIR5195 | n.36A>G | RNA (SNP) | VAF 67/143 reads (47%) | catalogued as rs1479660203; called by muse, mutect2, varscan2
- PDGFC | c.-511G>C | 5'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- RNA5-8SP2 | chr16:34159388 T>A | 5'Flank (SNP) | VAF 5/19 reads (26%) | catalogued as rs72797460; called by muse, mutect2, varscan2
- RNF207 | c.*1594C>T | 3'UTR (SNP) | VAF 29/209 reads (14%) | catalogued as rs1261851214; called by muse, mutect2, varscan2
- SIPA1L1 | c.*1032G>C | 3'UTR (SNP) | VAF 18/88 reads (20%) | called by mutect2, varscan2
- SLC25A43 | c.*275G>A | 3'UTR (SNP) | VAF 11/52 reads (21%) | catalogued as rs1456578622; called by muse, mutect2, varscan2
- SLC2A11 | c.21+531T>C | Intron (SNP) | VAF 40/96 reads (42%) | catalogued as rs1448537340; called by muse, mutect2, varscan2
- SLC6A5 | c.*1717T>C | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1891-42C>T | Intron (SNP) | VAF 18/50 reads (36%) | catalogued as rs761035492; called by muse, mutect2, varscan2
- TRIM64B | c.*656G>A | 3'UTR (SNP) | VAF 30/536 reads (6%) | called by muse, mutect2
- TTYH3 | c.*1869G>C | 3'UTR (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- YY1 | c.*2577A>C | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- ZNF680 | c.*1114C>G | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ZNF782 | c.*889G>T | 3'UTR (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- ZSCAN31 | c.-326-110G>A | Intron (SNP) | VAF 58/177 reads (33%) | called by muse, mutect2, varscan2
